CCDI case PBCKTM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1dfcbf9e-b91d-486b-831e-9bdb8acec423

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.9 years (2,514 days).

Biospecimens (3 samples)
- Sample 0DU7ZX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU80D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU81B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
